Somatic mutation profile of tumor specimen C3N-02940-01 (aliquot CPT0208550008) from CPTAC case C3N-02940, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.5 years (23,550 days).
Specimen C3N-02940-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e24b51c2-6128-4e82-af02-f89a0c696040.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02940-31 (Blood Derived Normal), aliquot CPT0208610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2425dbed-4ca9-4ab6-aa5e-44c2f13ba763

The open-access MAF lists 68 somatic variants for this specimen: 45 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Intron 2, 3'UTR 1, Splice Region 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/536 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 93/602 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4607C>T p.A1536V | Missense Mutation (SNP) | VAF 64/1081 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs745918247, CM118067, COSV56854756; ClinVar: uncertain significance; called by muse, mutect2
- ADAM30 | c.1715C>T p.T572M | Missense Mutation (SNP) | VAF 376/874 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs367708640; called by muse, mutect2, varscan2
- AR | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.855); catalogued as rs775392428; called by muse, mutect2
- CHRM3 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 37/508 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs200014816, COSV99698054; called by muse, mutect2
- CHST15 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs544235718, COSV60566624; called by muse, mutect2
- CLIP2 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535427245, COSV56281778; called by muse, mutect2
- CTNNA3 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 12/412 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV65530949; called by muse, mutect2
- CYP8B1 | c.1378C>G p.H460D | Missense Mutation (SNP) | VAF 44/719 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV60227133; called by muse, mutect2
- DCHS1 | c.9799G>A p.V3267I | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs530939498, COSV100197569; called by muse, mutect2
- DNAH9 | c.8450C>T p.P2817L | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370070428; called by muse, mutect2
- ENPEP | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 72/1126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV54458272; called by muse, mutect2
- FSTL5 | c.1916C>A p.T639K | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV60183216; called by muse, mutect2, varscan2
- GLIS1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs142254031; called by muse, mutect2, varscan2
- GNRH2 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 47/442 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs61729221; called by muse, mutect2, varscan2
- LHX6 | c.274G>A p.V92M (on ENST00000373755 / NM_001242334.2; = p.V121M on NM_014368.5) | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.426); catalogued as rs762036833; called by muse, mutect2
- LRCH2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1470042897, COSV57747909; called by muse, mutect2
- MRGPRX4 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV58590471; called by muse, mutect2
- MUC2 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 73/535 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs780476801; called by muse, mutect2, varscan2
- MYH7B | c.5113C>T p.R1705W | Missense Mutation (SNP) | VAF 19/440 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1247217032, COSV99328198; called by muse, mutect2
- NOS1 | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 28/379 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771520384, COSV100499775; called by muse, mutect2
- PDE1B | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 50/650 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs764032346, COSV54495233; called by muse, mutect2
- POM121L12 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 40/682 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs761437622, COSV101374907; called by muse, mutect2
- PTGIS | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 37/491 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs267605985; called by muse, mutect2
- RGS22 | c.1403A>G p.Y468C | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs1563687169; called by muse, mutect2
- SLC25A48 | c.898C>T p.R300W (on ENST00000650267; = p.R249= on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/382 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.962); catalogued as rs780395889; called by muse, mutect2
- TENM3 | c.3378C>T p.N1126= | Splice Region (SNP) | VAF 18/185 reads (10%) | catalogued as rs757218648; called by muse, mutect2, varscan2
- TMPRSS11A | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1037515820, COSV58356942; called by muse, mutect2
- TWIST1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as CM970033, CM980019; called by muse, mutect2
- UNC45B | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs774414887, COSV52098827; called by muse, mutect2
- CSNK2A3 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 39/708 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- CUZD1 | c.1178A>G p.Y393C | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- EPB41L3 | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 17/456 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- FCRLA | c.379G>T p.D127Y (on ENST00000367959; = p.D104Y on NM_032738.4) | Missense Mutation (SNP) | VAF 26/572 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- GPR180 | c.242A>T p.K81M | Missense Mutation (SNP) | VAF 13/356 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2
- MRRF | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 36/614 reads (6%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.451); called by muse, mutect2
- PDE3A | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- PIGA | c.996A>C p.R332S | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.097); called by muse, mutect2
- ROCK1 | c.3359G>A p.R1120K | Missense Mutation (SNP) | VAF 14/424 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.201); called by muse, mutect2
- SMC1B | c.1432A>C p.N478H | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SYNE1 | c.12513G>T p.M4171I (on ENST00000367255 / NM_182961.4; = p.M4100I on NM_033071.3) | Missense Mutation (SNP) | VAF 25/628 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- TDRD9 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2
- TTLL3 | c.689T>C p.F230S | Missense Mutation (SNP) | VAF 14/444 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by muse, mutect2
- USP19 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ADAMTS2 | c.3558C>T p.P1186= | Silent (SNP) | VAF 65/680 reads (10%) | called by muse, mutect2
- CCDC87 | c.2340G>A p.E780= | Silent (SNP) | VAF 23/376 reads (6%) | called by muse, mutect2
- DLGAP2 | c.900C>T p.D300= | Silent (SNP) | VAF 21/546 reads (4%) | catalogued as rs200420347, COSV70096649, COSV70102718; called by muse, mutect2
- DYNC1H1 | c.9246A>G p.S3082= | Silent (SNP) | VAF 73/1206 reads (6%) | called by muse, mutect2
- FMR1 | c.324A>C p.T108= | Silent (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- KCNQ3 | c.2499C>T p.L833= | Silent (SNP) | VAF 64/1482 reads (4%) | catalogued as rs773301064; ClinVar: likely benign; called by muse, mutect2
- MAP1S | c.969C>T p.D323= | Silent (SNP) | VAF 35/577 reads (6%) | called by muse, mutect2
- PCSK1 | c.1134C>T p.H378= | Silent (SNP) | VAF 44/934 reads (5%) | called by muse, mutect2
- PEG3 | c.3180C>T p.G1060= | Silent (SNP) | VAF 13/240 reads (5%) | catalogued as COSV55651259; called by muse, mutect2
- PRAMEF18 | c.420G>A p.R140= | Silent (SNP) | VAF 68/982 reads (7%) | called by muse, mutect2
- RHBDD1 | c.168G>A p.V56= | Silent (SNP) | VAF 22/594 reads (4%) | called by muse, mutect2
- RYR1 | c.2064C>T p.T688= | Silent (SNP) | VAF 278/755 reads (37%) | catalogued as rs764993324, COSV62087193, COSV62097525; called by muse, mutect2, varscan2
- SLIT1 | c.813C>T p.R271= | Silent (SNP) | VAF 20/280 reads (7%) | catalogued as rs774778879, COSV56586381; called by muse, mutect2
- SPHKAP | c.1701C>T p.A567= | Silent (SNP) | VAF 41/561 reads (7%) | catalogued as rs371211421; called by muse, mutect2
- STMND1 | c.759C>T p.N253= | Silent (SNP) | VAF 12/181 reads (7%) | catalogued as rs760258726; called by muse, mutect2
- TBC1D4 | c.2355C>T p.N785= | Silent (SNP) | VAF 50/455 reads (11%) | catalogued as rs527354382; called by muse, mutect2, varscan2
- TYR | c.237G>A p.S79= | Silent (SNP) | VAF 42/678 reads (6%) | catalogued as rs376813190; called by muse, mutect2
- XPNPEP3 | c.1038G>A p.T346= | Silent (SNP) | VAF 139/982 reads (14%) | catalogued as rs1471008631, COSV63210168; called by muse, mutect2, varscan2
- AC009039.2 | chr16:52084396 G>A | 5'Flank (SNP) | VAF 19/604 reads (3%) | catalogued as rs1171144234; called by muse, mutect2
- CD8A | c.*365G>C | 3'UTR (SNP) | VAF 17/402 reads (4%) | called by muse, mutect2
- DOCK1 | c.-32C>T | 5'UTR (SNP) | VAF 15/209 reads (7%) | called by muse, mutect2
- NRG1 | c.701-4797G>T | Intron (SNP) | VAF 26/264 reads (10%) | called by muse, mutect2
- TINF2 | c.1062-13G>T | Intron (SNP) | VAF 82/1413 reads (6%) | called by muse, mutect2
